Somatic mutation profile of tumor specimen TCGA-EJ-7331-01A (aliquot TCGA-EJ-7331-01A-11D-2114-08) from TCGA case TCGA-EJ-7331, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.2 years (23,458 days).
Specimen TCGA-EJ-7331-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58d3982a-af39-4fbf-b816-cb32393bfde0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7331-10A (Blood Derived Normal), aliquot TCGA-EJ-7331-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1acc973a-2887-4004-99f7-df9a7d6c8c7b

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 11, Silent 9, Frame Shift Del 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.3209G>A p.G1070E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs201003374, COSV55593339; called by muse, mutect2, varscan2
- ADAM18 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV55850873; called by muse, mutect2, varscan2
- BICD2 | c.2354C>G p.A785G | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63550025, COSV63550697; called by muse, mutect2, varscan2
- DCC | c.610C>A p.P204T | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV100498089; called by muse, varscan2
- EPG5 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.069); catalogued as rs764534620, COSV56346933, COSV56352658; called by muse, mutect2, varscan2
- GPKOW | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50243819; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs755377142, COSV56238058; called by muse, mutect2, varscan2
- KCNB2 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as rs1239743237, COSV101578732, COSV73050052; called by muse, mutect2, varscan2
- KDM6A | c.4176+1G>A p.X1392_splice | Splice Site (SNP) | VAF 34/72 reads (47%) | catalogued as COSV65040978, COSV65042971, COSV65043510; called by muse, mutect2, varscan2
- NKIRAS2 | c.500A>G p.K167R | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV56918164; called by muse, mutect2
- PCF11 | c.1777T>A p.S593T | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV53534756; called by muse, mutect2, varscan2
- SPEN | c.10909_10910del p.H3638Pfs*7 | Frame Shift Del (DEL) | VAF 61/386 reads (16%) | catalogued as rs972442854; called by pindel, varscan2
- TRIP10 | c.1398G>A p.A466= (on ENST00000313244 / NM_001288962.2; = p.A410= on NM_004240.4) | Splice Region (SNP) | VAF 37/222 reads (17%) | catalogued as rs1568256655, COSV55587487; called by muse, mutect2, varscan2
- ZNF846 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.674); catalogued as rs760740107, COSV67412266; called by muse, mutect2
- PARVG | c.101del p.P34Hfs*17 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- ADAM18 | c.1440C>T p.G480= | Silent (SNP) | VAF 56/278 reads (20%) | catalogued as rs1449031684, COSV55850889; called by muse, varscan2
- DYNC1I1 | c.1692T>C p.N564= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV61465853; called by muse, mutect2, varscan2
- HDAC9 | c.1065G>A p.T355= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs750426788, COSV67779032; called by muse, mutect2, varscan2
- KCNK3 | c.525C>T p.A175= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV57193525, COSV57194348; called by muse, mutect2, varscan2
- LRP6 | c.94C>A p.R32= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV54381119, COSV54384487; called by muse, mutect2, varscan2
- MROH1 | c.4599T>C p.A1533= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- SCN9A | c.3918A>T p.G1306= (on ENST00000303354; = p.G1295= on NM_002977.3) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV57616749; called by muse, mutect2, varscan2
- TACC2 | c.1704A>T p.G568= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV57763277; called by muse, mutect2, varscan2
- UBE2O | c.966C>T p.S322= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV60065307, COSV60066696; called by muse, mutect2, varscan2
